Somatic mutation profile of tumor specimen TARGET-20-PASFIT-09A (aliquot TARGET-20-PASFIT-09A-02D) from TARGET case TARGET-20-PASFIT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,572 days).
Specimen TARGET-20-PASFIT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ba97ae0-7d90-4f93-8c69-7a69964ff1ca.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASFIT-14A (Bone Marrow Normal), aliquot TARGET-20-PASFIT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7cac969-d930-4478-ba14-3604296bbe66

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 69/174 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD21 | c.372dup p.D125Rfs*2 | Frame Shift Ins (INS) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- CNTN5 | c.2832G>A p.T944= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as rs201981641, COSV54293987; called by muse, mutect2, varscan2
